Somatic mutation profile of tumor specimen TCGA-29-1781-01A (aliquot TCGA-29-1781-01A-01W-0633-09) from TCGA case TCGA-29-1781, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.6 years (25,404 days).
Specimen TCGA-29-1781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6121f811-bd66-44f8-be03-f444561c6ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1781-10A (Blood Derived Normal), aliquot TCGA-29-1781-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0ea976c-07d6-4b46-92d9-2ccf229df678

The open-access MAF lists 104 somatic variants for this specimen: 84 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 17, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 2, Translation Start Site 1, Frame Shift Ins 1, 3'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.1688A>G p.H563R | Missense Mutation (SNP) | VAF 163/318 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV62427128; called by muse, mutect2, varscan2
- APC | c.8381G>T p.S2794I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV57389610, COSV99970895; called by muse, mutect2, varscan2
- APEX1 | c.871_872del p.L291Vfs*6 | Frame Shift Del (DEL) | VAF 41/132 reads (31%) | catalogued as rs747329195; called by pindel, varscan2
- ARNTL | c.1702G>C p.D568H (on ENST00000403290 / NM_001297719.2; = p.D567H on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as COSV53402214; called by muse, mutect2, varscan2
- ART1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as rs1397587297, COSV51707751; called by muse, mutect2, varscan2
- ATP6V1C2 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55365894; called by muse, mutect2, varscan2
- BAHD1 | c.2220dup p.S741Lfs*19 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1360925612; called by pindel, varscan2
- BPTF | c.7234C>G p.Q2412E | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV58849159; called by muse, mutect2, varscan2
- C3orf20 | c.1565G>T p.R522L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53785375, COSV53786774; called by muse, mutect2, varscan2
- CAPN3 | c.2328C>A p.N776K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); catalogued as rs1165070691, COSV55522825; called by muse, mutect2, varscan2
- CASR | c.1523G>T p.C508F (on ENST00000490131; = p.C585F on NM_000388.4) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM165790, COSV56142237; called by muse, mutect2, varscan2
- CASZ1 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100680661; called by muse, mutect2
- CDH12 | c.2088C>A p.D696E | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66456968; called by muse, mutect2, varscan2
- CDK13 | c.2896T>A p.F966I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV99475001; called by muse, mutect2
- CERS3 | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as rs1270729518, COSV52575928; called by muse, mutect2, varscan2
- CHD3 | c.4030C>A p.R1344S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100390604; called by muse, mutect2
- COL11A1 | c.4432A>T p.T1478S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV62201709; called by muse, mutect2, varscan2
- COL6A3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs1475465672, COSV55114597; called by muse, varscan2
- CREB3L3 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV50248909; called by muse, mutect2
- CSMD3 | c.8581C>A p.H2861N (on ENST00000297405 / NM_001363185.1; = p.H2692N on NM_052900.3) | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs139266832, COSV52158034; called by muse, mutect2, varscan2
- CTAGE1 | c.642A>T p.R214S | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV66945344; called by muse, mutect2, varscan2
- DCC | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59143860; called by muse, mutect2, varscan2
- DDX58 | c.373T>C p.S125P | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65885164; called by muse, mutect2, varscan2
- DELE1 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 158/227 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52006955; called by muse, mutect2, varscan2
- DICER1 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV58629850; called by muse, mutect2, varscan2
- DNAH5 | c.868T>A p.W290R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444443; called by muse, mutect2
- DNM2 | c.1509C>G p.S503R | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV58973590; called by muse, mutect2, varscan2
- DYTN | c.1672G>C p.A558P | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71513353; called by muse, mutect2, varscan2
- ECSIT | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV52941168; called by muse, mutect2, varscan2
- ENPP2 | c.2268C>A p.Y756* (on ENST00000075322 / NM_001040092.3; = p.Y808* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 10/194 reads (5%) | catalogued as rs1018695519, COSV50033279; called by muse, mutect2
- ERO1A | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.024); catalogued as COSV67472262; called by muse, mutect2, varscan2
- FNIP2 | c.2594T>G p.V865G | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV52447208; called by muse, mutect2, varscan2
- FPR3 | c.523T>A p.Y175N | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as COSV59332689; called by muse, mutect2, varscan2
- FREM2 | c.7379C>G p.T2460R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99746596; called by muse, mutect2
- GJA8 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53791239; called by muse, mutect2, varscan2
- GJB5 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs747813567, COSV58357304; called by muse, mutect2, varscan2
- GSTO2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100086562; called by muse, mutect2
- HNRNPH2 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV54510819; called by muse, mutect2, varscan2
- HPF1 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV66423065; called by muse, mutect2, varscan2
- HSD3B7 | c.465C>G p.H155Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52682591; called by muse, mutect2, varscan2
- IL26 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57490351; called by muse, mutect2, varscan2
- IMPG1 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100774801; called by muse, mutect2
- INSC | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65413736; called by muse, mutect2, varscan2
- ITPR3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.923); catalogued as COSV65415713; called by muse, mutect2, varscan2
- KASH5 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV71358237, COSV71358598; called by muse, mutect2, varscan2
- KATNIP | c.2669G>T p.S890I | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV55193987; called by muse, mutect2, varscan2
- LPAR3 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.527); catalogued as COSV65455431; called by muse, mutect2, varscan2
- LRRC1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs538702416, COSV63829600; called by muse, mutect2, varscan2
- LRRC8B | c.174C>A p.C58* | Nonsense Mutation (SNP) | VAF 5/119 reads (4%) | catalogued as COSV100446407; called by muse, mutect2
- LRRTM2 | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 100/303 reads (33%) | catalogued as COSV51226057; called by muse, mutect2, varscan2
- MACF1 | c.18790C>G p.H6264D (on ENST00000372915; = p.H4309D on NM_012090.5) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV57149635; called by muse, mutect2, varscan2
- MDN1 | c.2986A>G p.T996A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65532073; called by muse, mutect2, varscan2
- MOGS | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99280805; called by muse, mutect2
- MYO18B | c.6647A>T p.K2216M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV59151899; called by muse, varscan2
- NCAPG2 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 95/154 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV51992698; called by muse, mutect2, varscan2
- NPFFR2 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV100440251, COSV100440687; called by muse, mutect2, varscan2
- OR4F6 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 391/946 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); catalogued as COSV61027775; called by muse, mutect2, varscan2
- OR5H1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV63403664; called by muse, mutect2, varscan2
- OR5I1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56889600; called by muse, mutect2, varscan2
- PEX12 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV56779129; called by muse, mutect2, varscan2
- PGAP1 | c.1027T>A p.L343I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV61330556; called by muse, mutect2, varscan2
- PIP5K1C | c.360C>G p.S120R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100094879; called by muse, mutect2
- PLXNA4 | c.3092A>T p.D1031V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV58166461; called by muse, mutect2, varscan2
- PRLHR | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as rs976084353, COSV53305515; called by muse, mutect2, varscan2
- PRPF38B | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100898250, COSV64224717; called by muse, mutect2, varscan2
- PTCH1 | c.4321C>T p.P1441S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs746800536, COSV59497939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNASEH1 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV100177002; called by muse, mutect2
- RRAGA | c.769T>A p.S257T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV65843815; called by muse, mutect2, varscan2
- SLC4A10 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55770441, COSV55804080; called by muse, mutect2, varscan2
- SMG7 | c.2642G>A p.R881K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.104); catalogued as COSV61630991, COSV61634881; called by muse, mutect2, varscan2
- SSMEM1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 102/123 reads (83%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs191908225, COSV52833532; called by muse, mutect2, varscan2
- TMEM255B | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747402032, COSV100943067, COSV64704592; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 27/48 reads (56%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRPV3 | c.829A>T p.I277F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56796652; called by muse, mutect2, varscan2
- WIPF1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765784451, COSV55821439; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1689G>C p.K563N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60159260; called by muse, mutect2, varscan2
- ZNF473 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV54525563; called by muse, mutect2, varscan2
- ZWILCH | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV57183977; called by muse, mutect2, varscan2
- ANKRD26 | c.1980_1985+13del p.X660_splice | Splice Site (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel
- CDC25A | c.1112_1137del p.G371Vfs*11 | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2
- NRBP1 | c.567-22_580del p.X189_splice | Splice Site (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel
- SDS | c.916_946del p.N307Rfs*6 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel
- TBC1D9 | c.683_689del p.S228Ifs*15 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- ANXA2 | c.351C>A p.S117= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV60318837, COSV60319371; called by muse, mutect2, varscan2
- APOB | c.690C>A p.G230= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs151096846; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID5A | c.1488C>A p.P496= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100673514; called by muse, varscan2
- AXL | c.534C>A p.V178= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1002465671, COSV56576178; called by muse, mutect2, varscan2
- CDK13 | c.2652G>T p.L884= | Silent (SNP) | VAF 74/501 reads (15%) | catalogued as COSV51707816; called by muse, mutect2, varscan2
- CYP7A1 | c.1203C>T p.Y401= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV56962896; called by muse, mutect2, varscan2
- GPR179 | c.3486C>T p.T1162= (on ENST00000621958; = p.T1161= on NM_001004334.4) | Silent (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- IMPDH2 | c.774T>C p.Y258= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV58709201; called by muse, mutect2, varscan2
- LMBRD2 | c.2043A>C p.G681= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV56953288; called by muse, mutect2, varscan2
- NLRP2 | c.2437C>T p.L813= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV54761580; called by muse, mutect2, varscan2
- NUP214 | c.210A>G p.Q70= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs746341047, COSV55991416; called by muse, mutect2, varscan2
- RECQL | c.378A>C p.P126= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV59086138; called by muse, mutect2, varscan2
- SAP18 | c.150T>C p.N50= (on ENST00000607003; = p.N69= on NM_005870.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV66822999; called by muse, mutect2, varscan2
- SMARCA2 | c.2028G>A p.Q676= | Silent (SNP) | VAF 74/337 reads (22%) | catalogued as COSV61814011; called by muse, mutect2, varscan2
- TNFSF4 | c.402T>C p.S134= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV56057907; called by muse, mutect2, varscan2
- TTC27 | c.1098G>A p.V366= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1452316231, COSV58657495; called by muse, mutect2, varscan2
- XPO6 | c.804A>T p.P268= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV58972666; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827103 C>T | 3'Flank (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- CFAP47 | c.5536-646G>A | Intron (SNP) | VAF 30/59 reads (51%) | catalogued as COSV57977344; called by muse, mutect2, varscan2
- MMP2 | c.*1G>T | 3'UTR (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99527372; called by muse, mutect2, varscan2
